Somatic mutation profile of tumor specimen ALCH-ABD5-TTP1-A (aliquot ALCH-ABD5-TTP1-A-2-0-D-A485-36) from ALCHEMIST case ALCH-ABD5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.9 years (27,000 days).
Specimen ALCH-ABD5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e95dbfb-67d6-4997-bfc2-39591af1053f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABD5-NB1-A (Blood Derived Normal), aliquot ALCH-ABD5-NB1-A-1-0-D-A485-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f2fc472-d32d-4d2d-96d4-85a4c0e1eb0d

The open-access MAF lists 44 somatic variants for this specimen: 32 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 9, Nonsense Mutation 3, Frame Shift Del 3, Intron 2, Splice Site 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL11A2 | c.4392+1G>A p.X1464_splice (on ENST00000341947 / NM_080680.3; = p.X1357_splice on NM_080679.2) | Splice Site (SNP) | VAF 13/114 reads (11%) | catalogued as rs750995470, CS951381, COSV59499666; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 822/1242 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- BCHE | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV100012006; called by muse, mutect2, varscan2
- HLA-C | c.883A>T p.T295S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.982); catalogued as rs752664590; called by muse, mutect2, varscan2
- NCKAP5 | c.3632C>T p.P1211L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs747116383; called by muse, mutect2, varscan2
- NLRP12 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759770066; called by muse, mutect2, varscan2
- PLEC | c.5195C>T p.S1732F (on ENST00000322810 / NM_201380.4; = p.S1622F on NM_000445.5) | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as rs1206944270; called by muse, mutect2, varscan2
- TMEM87A | c.684+2T>A p.X228_splice | Splice Site (SNP) | VAF 16/180 reads (9%) | catalogued as COSV67746903; called by muse, mutect2
- ATAD5 | c.3526C>T p.Q1176* | Nonsense Mutation (SNP) | VAF 15/105 reads (14%) | called by muse, mutect2, varscan2
- ATM | c.2420_2433del p.L807Yfs*3 | Frame Shift Del (DEL) | VAF 51/372 reads (14%) | called by mutect2, pindel, varscan2
- C4orf47 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2
- CABIN1 | c.2511_2515delinsA p.K838Sfs*54 | Frame Shift Del (DEL) | VAF 43/315 reads (14%) | called by pindel, varscan2*
- CABYR | c.1337A>G p.E446G | Missense Mutation (SNP) | VAF 43/512 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); called by muse, mutect2
- EHF | c.698C>A p.S233Y | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FCGR2C | c.139C>G p.P47A | Missense Mutation (SNP) | VAF 48/540 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- FLG2 | c.1868C>A p.S623Y | Missense Mutation (SNP) | VAF 64/545 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- FRAS1 | c.8479G>T p.D2827Y | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FURIN | c.1264C>T p.H422Y | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRIK5 | c.198C>A p.D66E | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- HSD3B2 | c.41T>A p.L14Q | Missense Mutation (SNP) | VAF 63/402 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGKV1-17 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 55/516 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- MOV10 | c.587A>T p.Y196F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); called by muse, varscan2
- PLD5 | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PLXNB2 | c.3191C>T p.P1064L | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.093); called by muse, mutect2
- RGMA | c.956G>T p.C319F | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RHOT2 | c.1241G>T p.R414L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPL19 | c.422A>C p.H141P | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- SLC4A1AP | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- TAS2R3 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 23/126 reads (18%) | called by muse, mutect2, varscan2
- TNRC6A | c.1501G>A p.G501S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- TP53 | c.574_581del p.Q192Yfs*14 | Frame Shift Del (DEL) | VAF 46/337 reads (14%) | called by mutect2, pindel, varscan2
- TRIO | c.2431C>T p.Q811* | Nonsense Mutation (SNP) | VAF 28/186 reads (15%) | called by muse, varscan2
- ADAM12 | c.2094C>T p.S698= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs778205214, COSV64112156; called by mutect2, varscan2
- ALDOA | c.498C>T p.G166= (on ENST00000642816 / NM_001243177.4; = p.G112= on NM_184041.5) | Silent (SNP) | VAF 52/440 reads (12%) | catalogued as rs145811469; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSMD3 | c.9126T>C p.S3042= (on ENST00000297405 / NM_001363185.1; = p.S2873= on NM_052900.3) | Silent (SNP) | VAF 28/486 reads (6%) | catalogued as COSV99824786; called by muse, mutect2
- CSN3 | c.273C>T p.A91= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as rs1039355693; called by muse, mutect2
- SEMA5B | c.2022G>A p.A674= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs778899118; called by muse, mutect2, varscan2
- SNTB2 | c.1551T>C p.C517= | Silent (SNP) | VAF 30/203 reads (15%) | called by muse, mutect2, varscan2
- STXBP2 | c.384G>A p.K128= | Silent (SNP) | VAF 34/178 reads (19%) | catalogued as rs750463059, COSV99657399; called by muse, mutect2, varscan2
- TBC1D2 | c.1218G>A p.L406= | Silent (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- TMEM132E | c.1584G>A p.P528= (on ENST00000321639; = p.P618= on NM_001304438.2) | Silent (SNP) | VAF 27/234 reads (12%) | catalogued as rs1378594317; called by muse, mutect2, varscan2
- CD37 | chr19:49332264 G>A | 5'Flank (SNP) | VAF 37/236 reads (16%) | called by muse, mutect2, varscan2
- GCKR | c.644+475C>T | Intron (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- NOX4 | c.1516-31A>G | Intron (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
